Somatic mutation profile of tumor specimen 0DJXQA from CCDI case PBBXLV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.4 years (6,709 days).
Specimen 0DJXQA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f725f755-2f9a-4e92-bfd8-9687221177ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJXRM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32f4619c-c626-4386-a2a7-1a6d0edc93a5

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Frame Shift Ins 2, 5'UTR 2, Frame Shift Del 2, Nonsense Mutation 1, In Frame Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1232C>T p.S411F (on ENST00000399959; = p.S412F on NM_001356.5) | Missense Mutation (SNP) | VAF 133/157 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV67863397; called by muse, mutect2, varscan2
- HMCN1 | c.2521G>T p.V841F | Missense Mutation (SNP) | VAF 218/499 reads (44%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.993); catalogued as COSV54918787; called by muse, mutect2, varscan2
- JADE3 | c.1836del p.R613Gfs*97 | Frame Shift Del (DEL) | VAF 200/294 reads (68%) | catalogued as COSV54469389; called by mutect2, pindel, varscan2
- MAST3 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 25/437 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs775545026, COSV99445355; called by muse, mutect2
- NBR1 | c.2609A>G p.Y870C | Missense Mutation (SNP) | VAF 126/308 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs369015680; called by muse, mutect2, varscan2
- PHACTR2 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 141/325 reads (43%) | catalogued as rs563780647; called by muse, mutect2, varscan2
- PLPPR5 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 192/378 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs762283171; called by muse, mutect2, varscan2
- PTCH1 | c.1459_1464dup p.L487_C488dup | In Frame Ins (INS) | VAF 330/387 reads (85%) | catalogued as CI055019; called by mutect2, varscan2
- TCEAL3 | c.468dup p.Q157Tfs*33 | Frame Shift Ins (INS) | VAF 176/396 reads (44%) | catalogued as rs1485305343; called by pindel, varscan2
- USB1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 190/423 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199886884, COSV54682697; called by muse, mutect2, varscan2
- AFDN | c.1888T>C p.F630L | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DENND5B | c.2361G>T p.R787S | Missense Mutation (SNP) | VAF 205/404 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EMX1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 184/462 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS8L3 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 19/604 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- FAM171A2 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 139/313 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OFD1 | c.2686_2689del p.R896Gfs*9 | Frame Shift Del (DEL) | VAF 144/164 reads (88%) | called by pindel, varscan2
- PRKCG | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 263/577 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- XPO1 | c.1630dup p.I544Nfs*24 | Frame Shift Ins (INS) | VAF 143/388 reads (37%) | called by mutect2, pindel, varscan2
- ADCY2 | c.606C>T p.N202= | Silent (SNP) | VAF 136/365 reads (37%) | catalogued as rs1282519774, COSV57879153; called by muse, mutect2, varscan2
- FLOT1 | c.942G>A p.A314= | Silent (SNP) | VAF 212/516 reads (41%) | called by muse, mutect2, varscan2
- GEMIN5 | c.4218G>A p.P1406= | Silent (SNP) | VAF 217/527 reads (41%) | catalogued as rs1368276840; called by muse, mutect2, varscan2
- MUC5AC | c.4389G>A p.S1463= | Silent (SNP) | VAF 73/156 reads (47%) | catalogued as rs1465880502; called by muse, mutect2, varscan2
- UNC13C | c.5907T>C p.G1969= | Silent (SNP) | VAF 150/342 reads (44%) | catalogued as rs1486760603; called by muse, mutect2, varscan2
- AKT1 | c.-27G>C | 5'UTR (SNP) | VAF 102/241 reads (42%) | catalogued as rs768619756; called by muse, mutect2, varscan2
- CDK5 | c.-32G>A | 5'UTR (SNP) | VAF 106/242 reads (44%) | catalogued as rs761027432; called by muse, mutect2, varscan2
- JUND | c.*29C>A | 3'UTR (SNP) | VAF 63/175 reads (36%) | called by muse, mutect2
- RUNX1 | c.724+12835G>A | Intron (SNP) | VAF 70/163 reads (43%) | catalogued as rs538168358; called by muse, mutect2, varscan2
